Somatic mutation profile of tumor specimen TCGA-V4-A9F2-01A (aliquot TCGA-V4-A9F2-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F2, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Ciliary body; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 78.9 years (28,832 days).
Specimen TCGA-V4-A9F2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07d00197-d3a4-4099-b13a-d939faab26d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F2-10A (Blood Derived Normal), aliquot TCGA-V4-A9F2-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95b34393-eaaf-4f48-95fe-b6a7087a0f21

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF17 | c.1381T>G p.S461A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ITPKB | c.1862G>C p.S621T | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MRPS35 | c.96C>T p.V32= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs887984082; called by muse, mutect2, varscan2
